Somatic mutation profile of cancer-model specimen HCM-CSHL-0808-C55-85A (3D Organoid, passage 14; aliquot HCM-CSHL-0808-C55-85A-01D-A881-36), derived from the primary tumor of HCMI case HCM-CSHL-0808-C55, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; AJCC pathologic stage: Stage IIIC2; FIGO stage: Stage IIIC2.
Specimen HCM-CSHL-0808-C55-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 14.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5456f95c-5fc1-41d9-a5af-b74b15ee4ddf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0808-C55-11A (Solid Tissue Normal), aliquot HCM-CSHL-0808-C55-11A-01D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d86a4b55-8024-4ea5-8a8c-c4e19e2fd7cc

The open-access MAF lists 261 somatic variants for this specimen: 189 protein-altering or splice-affecting, 64 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 167, Silent 64, Nonsense Mutation 10, 3'UTR 5, In Frame Del 3, Frame Shift Del 3, Splice Region 2, Splice Site 2, Frame Shift Ins 2, 5'UTR 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PPP2R1A | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 383/687 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59042523, COSV59042723; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 297/299 reads (99%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TPO | c.2077C>T p.R693W | Missense Mutation (SNP) | VAF 242/1301 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs121908087, CM002645, COSV100221850, COSV61106041; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACACA | c.6524G>A p.R2175H | Missense Mutation (SNP) | VAF 356/505 reads (70%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.917); catalogued as rs145087711; called by muse, mutect2, varscan2
- ADGRG4 | c.6289G>T p.D2097Y | Missense Mutation (SNP) | VAF 245/480 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV54957324; called by muse, mutect2, varscan2
- ADNP | c.1041G>A p.M347I | Missense Mutation (SNP) | VAF 130/423 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV62426100; called by muse, mutect2, varscan2
- ANKRD11 | c.5254C>G p.P1752A | Missense Mutation (SNP) | VAF 124/1296 reads (10%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV56370386; called by muse, mutect2
- ARMH1 | c.902C>T p.A301V | Missense Mutation (SNP) | VAF 82/662 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs1219316962; called by muse, mutect2, varscan2
- C6 | c.1991T>A p.V664D | Missense Mutation (SNP) | VAF 19/515 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV54718532, COSV99667483; called by muse, mutect2
- CALML3 | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 237/742 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs751919507, COSV100178722; called by muse, mutect2, varscan2
- CCDC141 | c.148C>G p.L50V | Missense Mutation (SNP) | VAF 60/718 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.321); catalogued as rs1187862504; called by muse, mutect2
- CCDC6 | c.194C>T p.S65L | Missense Mutation (SNP) | VAF 179/886 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.901); catalogued as rs1317179840, COSV54059665; called by muse, mutect2, varscan2
- CDH7 | c.1468G>A p.V490I | Missense Mutation (SNP) | VAF 131/245 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as rs761625164; called by muse, mutect2, varscan2
- CENPU | c.958A>G p.M320V | Missense Mutation (SNP) | VAF 152/153 reads (99%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs141051170; called by muse, varscan2
- CHSY1 | c.2135C>G p.S712C | Missense Mutation (SNP) | VAF 124/918 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54254496; called by muse, mutect2, varscan2
- CIB3 | c.100T>A p.Y34N | Missense Mutation (SNP) | VAF 50/422 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV99521695; called by muse, mutect2, varscan2
- CLIP2 | c.2446G>C p.E816Q | Missense Mutation (SNP) | VAF 60/1086 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.15); catalogued as COSV56279986; called by muse, mutect2
- CR1 | c.5582G>C p.G1861A | Missense Mutation (SNP) | VAF 110/513 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.075); catalogued as COSV65458138; called by muse, mutect2, varscan2
- CUL2 | c.1325G>A p.R442H | Missense Mutation (SNP) | VAF 36/257 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66078682; called by muse, mutect2, varscan2
- DENND5B | c.1672C>G p.L558V | Missense Mutation (SNP) | VAF 95/373 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV104405549; called by muse, mutect2, varscan2
- DERL2 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 34/304 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs776489021; called by muse, mutect2, varscan2
- DNAJC21 | c.168G>C p.L56F | Missense Mutation (SNP) | VAF 76/332 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100331271; called by muse, mutect2, varscan2
- DYSF | c.2113G>T p.V705L | Missense Mutation (SNP) | VAF 110/623 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as CM138634; called by muse, mutect2, varscan2
- EHBP1L1 | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 132/857 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1279762999; called by muse, mutect2, varscan2
- EPHA3 | c.2590G>A p.D864N | Missense Mutation (SNP) | VAF 88/441 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.357); catalogued as COSV60714323; called by muse, mutect2, varscan2
- FAM170B | c.435G>C p.K145N | Missense Mutation (SNP) | VAF 204/692 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as rs569542018; called by muse, mutect2, varscan2
- FAT1 | c.2173C>T p.Q725* | Nonsense Mutation (SNP) | VAF 27/342 reads (8%) | catalogued as COSV71675113; called by muse, mutect2
- FCSK | c.2852C>G p.A951G | Missense Mutation (SNP) | VAF 52/874 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.626); catalogued as rs1482555569, COSV55368664; called by muse, mutect2
- GMIP | c.2573G>T p.G858V | Missense Mutation (SNP) | VAF 34/1350 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as COSV99179655; called by muse, mutect2
- GNAI1 | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 52/303 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as COSV63522486; called by muse, mutect2, varscan2
- HAPLN1 | c.286G>T p.V96F | Missense Mutation (SNP) | VAF 58/554 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs78290665; called by muse, mutect2
- HEG1 | c.146G>A p.G49E | Missense Mutation (SNP) | VAF 74/786 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.055); catalogued as rs1440908812; called by muse, mutect2
- HUWE1 | c.1042G>A p.D348N | Missense Mutation (SNP) | VAF 168/562 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53354372; called by muse, mutect2, varscan2
- IL1RAPL2 | c.931G>C p.E311Q | Missense Mutation (SNP) | VAF 149/278 reads (54%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.929); catalogued as COSV100781913, COSV61160693, COSV61187040; called by muse, mutect2, varscan2
- IRF4 | c.360C>G p.D120E | Missense Mutation (SNP) | VAF 126/567 reads (22%) | SIFT tolerated (0.71); PolyPhen benign (0.04); catalogued as rs1320369594; called by muse, mutect2, varscan2
- KIAA1522 | c.2950C>T p.R984* (on ENST00000373480 / NM_001198972.2; = p.R1043* on NM_020888.3) | Nonsense Mutation (SNP) | VAF 132/549 reads (24%) | catalogued as rs1557438928, COSV53866023; called by muse, mutect2, varscan2
- KIF11 | c.1006A>G p.I336V | Missense Mutation (SNP) | VAF 140/329 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs761471421, COSV53268671; called by muse, mutect2, varscan2
- KLHL34 | c.1469C>T p.A490V | Missense Mutation (SNP) | VAF 286/724 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0.207); catalogued as COSV65278709; called by muse, mutect2, varscan2
- LMTK2 | c.377-1G>A p.X126_splice | Splice Site (SNP) | VAF 116/1055 reads (11%) | catalogued as COSV99807141; called by muse, mutect2, varscan2
- MFSD8 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 75/577 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.017); catalogued as COSV99614758; called by muse, mutect2, varscan2
- NAP1L3 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 150/453 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59075361; called by muse, varscan2
- NCKAP5 | c.4876G>T p.D1626Y | Missense Mutation (SNP) | VAF 28/408 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100491579; called by muse, mutect2
- PGRMC1 | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 283/578 reads (49%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs1179307251; called by muse, mutect2, varscan2
- PIK3CA | c.334A>T p.I112F | Missense Mutation (SNP) | VAF 379/482 reads (79%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.719); catalogued as COSV55908000; called by muse, mutect2, varscan2
- PLK5 | c.217C>T p.R73W | Missense Mutation (SNP) | VAF 340/347 reads (98%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs186235308; called by muse, mutect2, varscan2
- PP2D1 | c.213C>A p.H71Q | Missense Mutation (SNP) | VAF 435/437 reads (100%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60748589; called by muse, mutect2, varscan2
- PROKR1 | c.1042G>T p.D348Y | Missense Mutation (SNP) | VAF 292/675 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV58137109; called by mutect2, varscan2
- PROX1 | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 144/634 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV54775943; called by muse, mutect2, varscan2
- PTGER3 | c.1145C>T p.T382I | Missense Mutation (SNP) | VAF 96/360 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs768023105; called by muse, mutect2, varscan2
- RLIM | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 376/582 reads (65%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as COSV100223354; called by muse, mutect2, varscan2
- RMC1 | c.468G>C p.W156C | Missense Mutation (SNP) | VAF 52/970 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs758501055; called by muse, mutect2
- ROS1 | c.5872G>A p.E1958K | Missense Mutation (SNP) | VAF 117/984 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs986549979; called by muse, mutect2, varscan2
- SBNO2 | c.730A>C p.S244R | Missense Mutation (SNP) | VAF 538/1522 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as COSV100684226; called by mutect2, varscan2
- SLC35F1 | c.698C>T p.S233F | Missense Mutation (SNP) | VAF 148/951 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64499146, COSV64503401; called by muse, mutect2, varscan2
- SLC6A15 | c.273T>A p.C91* | Nonsense Mutation (SNP) | VAF 18/473 reads (4%) | catalogued as COSV99880314; called by muse, mutect2
- SPAG17 | c.343G>C p.D115H | Missense Mutation (SNP) | VAF 79/335 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV60454735; called by muse, mutect2, varscan2
- SPRY3 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 353/699 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV57141687; called by muse, mutect2, varscan2
- TACR1 | c.1189G>C p.E397Q | Missense Mutation (SNP) | VAF 88/696 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.26); catalogued as COSV59483701; called by muse, mutect2, varscan2
- TAF2 | c.1950G>C p.Q650H | Missense Mutation (SNP) | VAF 86/866 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.189); catalogued as rs1306602704; called by muse, mutect2
- TMEM31 | c.503_505del p.F168del | In Frame Del (DEL) | VAF 39/179 reads (22%) | catalogued as rs1243080445; called by pindel, varscan2
- TMEM39A | c.1279A>G p.I427V | Missense Mutation (SNP) | VAF 48/432 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.464); catalogued as rs781747883; called by muse, mutect2, varscan2
- TPRG1 | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 66/450 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.374); catalogued as COSV100800863; called by muse, mutect2, varscan2
- TRAF3IP1 | c.1031C>G p.T344R | Missense Mutation (SNP) | VAF 50/498 reads (10%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.459); catalogued as COSV64854220; called by muse, mutect2, varscan2
- TREML2 | c.751C>G p.L251V | Missense Mutation (SNP) | VAF 146/564 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs185375765; called by muse, mutect2, varscan2
- TRPV2 | c.2257G>A p.E753K | Missense Mutation (SNP) | VAF 186/387 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.146); catalogued as rs776782532; called by muse, mutect2, varscan2
- USP31 | c.3965C>T p.S1322L | Missense Mutation (SNP) | VAF 88/417 reads (21%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs752774550; called by muse, mutect2, varscan2
- WNT3A | c.789C>A p.F263L | Missense Mutation (SNP) | VAF 27/843 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.262); catalogued as COSV52728202, COSV52728612; called by muse, mutect2
- ZEB2 | c.649G>A p.D217N | Missense Mutation (SNP) | VAF 49/556 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as rs755199698, COSV57956903; called by muse, mutect2
- ZNF493 | c.1205C>G p.S402* | Nonsense Mutation (SNP) | VAF 73/518 reads (14%) | catalogued as COSV62750136; called by muse, mutect2, varscan2
- ZNF675 | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 65/330 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.555); catalogued as rs370887480; called by muse, mutect2, varscan2
- ZNF773 | c.516G>T p.E172D | Missense Mutation (SNP) | VAF 244/397 reads (61%) | SIFT tolerated (0.56); PolyPhen benign (0.017); catalogued as COSV56589303; called by muse, mutect2, varscan2
- ABCB4 | c.2307C>A p.F769L | Missense Mutation (SNP) | VAF 89/456 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- ADGRA3 | c.508C>G p.Q170E | Missense Mutation (SNP) | VAF 31/342 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.065); called by muse, mutect2
- AGTR1 | c.763C>A p.P255T | Missense Mutation (SNP) | VAF 99/635 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AHCTF1 | c.4657C>G p.Q1553E (on ENST00000366508; = p.Q1527E on NM_015446.5) | Missense Mutation (SNP) | VAF 55/279 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ALMS1 | c.7046A>C p.E2349A | Missense Mutation (SNP) | VAF 44/714 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.104); called by muse, mutect2
- AMBRA1 | c.2303C>T p.S768L (on ENST00000458649 / NM_001367468.1; = p.S678L on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 122/262 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ANAPC4 | c.608_619del p.G203_L206del | In Frame Del (DEL) | VAF 111/249 reads (45%) | called by mutect2, pindel, varscan2
- ANKRD35 | c.2105G>A p.R702Q | Missense Mutation (SNP) | VAF 105/730 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AP3B1 | c.2488C>G p.P830A | Missense Mutation (SNP) | VAF 160/161 reads (99%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- APBA2 | c.329A>G p.Y110C | Missense Mutation (SNP) | VAF 94/783 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARHGAP33 | c.2452C>G p.L818V | Missense Mutation (SNP) | VAF 70/1007 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- ARMH2 | c.123G>T p.K41N | Missense Mutation (SNP) | VAF 178/634 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- BIRC6 | c.7A>G p.T3A | Missense Mutation (SNP) | VAF 182/471 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- C5orf49 | c.4G>C p.E2Q | Missense Mutation (SNP) | VAF 56/926 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.426); called by muse, mutect2
- C6orf141 | c.394T>C p.S132P | Missense Mutation (SNP) | VAF 28/686 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.028); called by muse, mutect2
- CBLIF | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 112/358 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- CCDC168 | c.1564A>G p.K522E | Missense Mutation (SNP) | VAF 63/294 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- CD36 | c.485T>A p.I162N | Missense Mutation (SNP) | VAF 42/764 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.938); called by muse, mutect2
- CEL | c.2153C>G p.P718R (on ENST00000673714; = p.P715R on NM_001807.6) | Missense Mutation (SNP) | VAF 72/389 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- CENPU | c.944A>C p.K315T | Missense Mutation (SNP) | VAF 136/136 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, varscan2
- CFAP221 | c.897G>T p.K299N | Missense Mutation (SNP) | VAF 14/467 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.117); called by muse, mutect2
- CFAP54 | c.415C>T p.Q139* | Nonsense Mutation (SNP) | VAF 67/260 reads (26%) | called by muse, mutect2, varscan2
- CFHR1 | c.252C>T p.L84= | Splice Region (SNP) | VAF 75/300 reads (25%) | called by muse, mutect2, varscan2
- CLHC1 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 65/382 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- CPEB3 | c.399dup p.M134Hfs*188 | Frame Shift Ins (INS) | VAF 370/832 reads (44%) | called by mutect2, pindel, varscan2
- CREBRF | c.762G>T p.Q254H | Missense Mutation (SNP) | VAF 196/627 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- CUL7 | c.4114G>A p.E1372K | Missense Mutation (SNP) | VAF 213/799 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- DCDC2C | c.629C>A p.T210N | Missense Mutation (SNP) | VAF 19/723 reads (3%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2
- DEUP1 | c.1699G>C p.E567Q | Missense Mutation (SNP) | VAF 150/377 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- DIPK1B | c.1277C>G p.S426C | Missense Mutation (SNP) | VAF 88/371 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DMTF1 | c.2128G>C p.D710H | Missense Mutation (SNP) | VAF 96/739 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- DMXL2 | c.6869A>T p.Y2290F | Missense Mutation (SNP) | VAF 57/295 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- EPPK1 | c.1875C>A p.S625R | Missense Mutation (SNP) | VAF 131/764 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- ESF1 | c.139T>G p.F47V | Missense Mutation (SNP) | VAF 96/732 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FAM13A | c.1536G>A p.R512= | Splice Region (SNP) | VAF 155/295 reads (53%) | called by muse, mutect2, varscan2
- FXR1 | c.1395C>G p.I465M | Missense Mutation (SNP) | VAF 114/474 reads (24%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- GABRG3 | c.926G>A p.R309H | Missense Mutation (SNP) | VAF 183/510 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, varscan2
- GCC2 | c.1789G>C p.D597H | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- GPATCH1 | c.1001-1G>A p.X334_splice | Splice Site (SNP) | VAF 212/542 reads (39%) | called by muse, mutect2, varscan2
- GPRC5D | c.716A>T p.D239V | Missense Mutation (SNP) | VAF 70/704 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GRPR | c.465G>T p.M155I | Missense Mutation (SNP) | VAF 232/734 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.024); called by muse, mutect2
- GSN | c.1804G>T p.A602S | Missense Mutation (SNP) | VAF 68/362 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- GTF2IRD1 | c.2826C>A p.Y942* (on ENST00000265755 / NM_016328.3; = p.Y927* on NM_005685.4) | Nonsense Mutation (SNP) | VAF 175/798 reads (22%) | called by muse, mutect2, varscan2
- HLA-DMA | c.711del p.F237Lfs*58 | Frame Shift Del (DEL) | VAF 387/919 reads (42%) | called by mutect2, pindel, varscan2
- HRNR | c.806G>C p.R269T | Missense Mutation (SNP) | VAF 106/1110 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.017); called by muse, mutect2
- HSPBP1 | c.605_616del p.D202_R205del | In Frame Del (DEL) | VAF 64/662 reads (10%) | called by mutect2, pindel
- HTR1A | c.919C>G p.L307V | Missense Mutation (SNP) | VAF 76/443 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- HUWE1 | c.8988del p.T2997Lfs*18 | Frame Shift Del (DEL) | VAF 92/698 reads (13%) | called by mutect2, pindel, varscan2
- IGF1R | c.3807G>T p.E1269D | Missense Mutation (SNP) | VAF 26/1084 reads (2%) | SIFT tolerated (0.97); PolyPhen benign (0); called by muse, mutect2
- IPO7 | c.958C>T p.R320* | Nonsense Mutation (SNP) | VAF 72/198 reads (36%) | called by muse, mutect2, varscan2
- KCNG4 | c.1274T>G p.V425G | Missense Mutation (SNP) | VAF 44/1381 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- KDM8 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 80/464 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- KIF2B | c.1012C>T p.L338F | Missense Mutation (SNP) | VAF 133/426 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- KIFBP | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 164/635 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- KLF18 | c.662G>T p.G221V | Missense Mutation (SNP) | VAF 21/602 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); called by muse, mutect2
- KRT81 | c.1087G>T p.D363Y | Missense Mutation (SNP) | VAF 213/985 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LCOR | c.1273C>A p.Q425K | Missense Mutation (SNP) | VAF 28/402 reads (7%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); called by muse, mutect2
- LCOR | c.3394G>A p.G1132R | Missense Mutation (SNP) | VAF 116/416 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- LTBP3 | c.3868C>T p.R1290C (on ENST00000301873 / NM_001130144.3; = p.R1243C on NM_021070.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 498/1043 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAGEB6B | c.745G>C p.G249R | Missense Mutation (SNP) | VAF 76/477 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- MAN2B2 | c.2725G>C p.D909H | Missense Mutation (SNP) | VAF 254/424 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- MEIG1 | c.130G>A p.V44I | Missense Mutation (SNP) | VAF 23/216 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- METTL25 | c.453G>A p.M151I | Missense Mutation (SNP) | VAF 72/263 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- MICAL1 | c.973G>T p.V325L | Missense Mutation (SNP) | VAF 99/915 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- MIPEP | c.969dup p.L324Tfs*3 | Frame Shift Ins (INS) | VAF 30/214 reads (14%) | called by pindel, varscan2
- MIPEP | c.964G>C p.E322Q | Missense Mutation (SNP) | VAF 30/203 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.021); called by muse, varscan2
- MYBPC2 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 60/640 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MYH8 | c.3160G>T p.A1054S | Missense Mutation (SNP) | VAF 18/362 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2
- MYO1F | c.2942C>G p.P981R | Missense Mutation (SNP) | VAF 24/510 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2
- NEB | c.3023A>C p.N1008T | Missense Mutation (SNP) | VAF 38/461 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- NOL4 | c.769G>C p.D257H | Missense Mutation (SNP) | VAF 132/358 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NUP188 | c.3599A>C p.E1200A | Missense Mutation (SNP) | VAF 264/440 reads (60%) | SIFT tolerated (0.11); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- NUTM2G | c.547C>G p.H183D | Missense Mutation (SNP) | VAF 216/1008 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- OR1L3 | c.461T>C p.F154S | Missense Mutation (SNP) | VAF 60/300 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- OR2V1 | c.705del p.W235* | Frame Shift Del (DEL) | VAF 138/588 reads (23%) | called by mutect2, pindel, varscan2
- PAIP1 | c.1174G>T p.E392* | Nonsense Mutation (SNP) | VAF 30/486 reads (6%) | called by muse, mutect2
- PCDH17 | c.2416C>T p.L806F | Missense Mutation (SNP) | VAF 117/529 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- PCLO | c.3347C>T p.S1116L | Missense Mutation (SNP) | VAF 109/801 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PDZRN3 | c.2805G>C p.K935N | Missense Mutation (SNP) | VAF 92/691 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PGR | c.2112C>A p.D704E | Missense Mutation (SNP) | VAF 78/387 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PGRMC2 | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 120/428 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.727); called by muse, mutect2, varscan2
- PHIP | c.5176G>A p.D1726N | Missense Mutation (SNP) | VAF 116/538 reads (22%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- PLA2G7 | c.1018G>C p.E340Q | Missense Mutation (SNP) | VAF 52/178 reads (29%) | SIFT tolerated (0.8); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- PPM1H | c.946C>G p.Q316E | Missense Mutation (SNP) | VAF 88/299 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRSS12 | c.605C>G p.S202C | Missense Mutation (SNP) | VAF 106/358 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PSG2 | c.491C>A p.T164N | Missense Mutation (SNP) | VAF 41/472 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.756); called by muse, mutect2
- PSME4 | c.23G>T p.G8V | Missense Mutation (SNP) | VAF 54/715 reads (8%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.021); called by muse, mutect2
- PTGES3L-AARSD1 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 45/394 reads (11%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PTPN23 | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 631/635 reads (99%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- RASEF | c.1620G>T p.K540N | Missense Mutation (SNP) | VAF 44/316 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- RELB | c.1311A>C p.K437N | Missense Mutation (SNP) | VAF 61/1274 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.048); called by muse, mutect2
- SDCCAG8 | c.466G>C p.E156Q | Missense Mutation (SNP) | VAF 122/552 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- SLC6A15 | c.274C>A p.Q92K | Missense Mutation (SNP) | VAF 18/468 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.973); called by muse, mutect2
- SMPD3 | c.814G>T p.G272C | Missense Mutation (SNP) | VAF 38/1400 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.241); called by muse, mutect2
- SOBP | c.1873C>T p.R625W | Missense Mutation (SNP) | VAF 24/776 reads (3%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.525); called by muse, mutect2
- SPATA31A3 | c.353C>G p.S118C | Missense Mutation (SNP) | VAF 62/702 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.896); called by muse, mutect2
- SPTA1 | c.572A>G p.E191G | Missense Mutation (SNP) | VAF 48/732 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SRBD1 | c.2582C>T p.S861L | Missense Mutation (SNP) | VAF 96/526 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SRD5A1 | c.154G>T p.A52S | Missense Mutation (SNP) | VAF 110/1782 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.119); called by muse, mutect2
- SSH2 | c.434G>A p.W145* | Nonsense Mutation (SNP) | VAF 19/516 reads (4%) | called by muse, mutect2
- ST3GAL4 | c.710T>C p.M237T (on ENST00000392669 / NM_001254758.1; = p.M233T on NM_006278.3) | Missense Mutation (SNP) | VAF 29/560 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.069); called by muse, mutect2
- STUB1 | c.854C>A p.A285D | Missense Mutation (SNP) | VAF 53/418 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TAF11L12 | c.180A>C p.E60D | Missense Mutation (SNP) | VAF 115/626 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TBX22 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 23/624 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.06); called by muse, mutect2
- TJP1 | c.656G>C p.R219T | Missense Mutation (SNP) | VAF 124/364 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- TMEM131 | c.4541G>C p.G1514A | Missense Mutation (SNP) | VAF 34/460 reads (7%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.003); called by muse, mutect2
- TMEM161A | c.863T>A p.I288N | Missense Mutation (SNP) | VAF 149/579 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- TMEM8B | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 201/507 reads (40%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- TMTC2 | c.1295G>A p.C432Y | Missense Mutation (SNP) | VAF 44/554 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- TNK2 | c.553G>C p.D185H | Missense Mutation (SNP) | VAF 171/867 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TRGV11 | c.226C>T p.H76Y | Missense Mutation (SNP) | VAF 111/455 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- UBE2E1 | c.554G>A p.R185K | Missense Mutation (SNP) | VAF 16/394 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.012); called by muse, mutect2
- UHRF1BP1L | c.823G>T p.A275S | Missense Mutation (SNP) | VAF 44/357 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- XIRP2 | c.3761A>T p.N1254I (on ENST00000628543; = p.N1429I on NM_152381.6) | Missense Mutation (SNP) | VAF 28/381 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.459); called by muse, mutect2
- XPOT | c.2756T>A p.L919H | Missense Mutation (SNP) | VAF 13/389 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZDHHC11 | c.532A>G p.T178A | Missense Mutation (SNP) | VAF 52/1184 reads (4%) | SIFT tolerated (0.62); PolyPhen benign (0.012); called by muse, mutect2
- ZFP28 | c.1951A>T p.S651C | Missense Mutation (SNP) | VAF 70/576 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- ZNF878 | c.1567C>T p.Q523* | Nonsense Mutation (SNP) | VAF 133/561 reads (24%) | called by muse, mutect2, varscan2
- ADGRB2 | c.1011G>T p.V337= | Silent (SNP) | VAF 81/1227 reads (7%) | called by muse, mutect2
- AL772284.1 | c.99C>T p.G33= | Silent (SNP) | VAF 196/413 reads (47%) | catalogued as rs1357803202; called by muse, varscan2
- BCAR3 | c.331C>T p.L111= | Silent (SNP) | VAF 90/412 reads (22%) | called by muse, mutect2, varscan2
- BRINP3 | c.301C>T p.L101= | Silent (SNP) | VAF 134/625 reads (21%) | called by muse, mutect2, varscan2
- BRPF3 | c.873G>A p.V291= | Silent (SNP) | VAF 94/686 reads (14%) | called by muse, mutect2, varscan2
- CBFA2T3 | c.843A>C p.S281= | Silent (SNP) | VAF 76/1234 reads (6%) | called by muse, mutect2
- CDH18 | c.1317C>T p.T439= | Silent (SNP) | VAF 274/660 reads (42%) | catalogued as COSV56970694; called by muse, mutect2, varscan2
- CDH23 | c.4671C>T p.I1557= | Silent (SNP) | VAF 205/605 reads (34%) | catalogued as rs182260167, COSV56481282; called by muse, mutect2, varscan2
- CENPQ | c.372G>A p.L124= | Silent (SNP) | VAF 59/248 reads (24%) | catalogued as rs747639319; called by muse, mutect2, varscan2
- CHST15 | c.1209C>G p.L403= | Silent (SNP) | VAF 67/441 reads (15%) | catalogued as rs766279667, COSV60564672; called by muse, mutect2, varscan2
- CORO7 | c.1806C>T p.F602= | Silent (SNP) | VAF 65/639 reads (10%) | catalogued as rs748441617; called by muse, mutect2, varscan2
- DAP3 | c.90A>G p.Q30= | Silent (SNP) | VAF 155/658 reads (24%) | called by muse, mutect2, varscan2
- DERA | c.747C>T p.N249= | Silent (SNP) | VAF 28/305 reads (9%) | called by muse, mutect2
- DLL1 | c.21G>A p.L7= | Silent (SNP) | VAF 22/661 reads (3%) | called by muse, mutect2
- FAM184A | c.2076T>C p.D692= | Silent (SNP) | VAF 44/624 reads (7%) | called by muse, mutect2
- FLII | c.12C>G p.T4= | Silent (SNP) | VAF 382/688 reads (56%) | called by muse, mutect2, varscan2
- GMIP | c.2574G>T p.G858= | Silent (SNP) | VAF 33/1364 reads (2%) | called by muse, mutect2
- GPT | c.342G>T p.A114= | Silent (SNP) | VAF 180/591 reads (30%) | catalogued as COSV52952235, COSV52952313, COSV99477330; called by muse, mutect2, varscan2
- GRID2 | c.2937A>C p.I979= | Silent (SNP) | VAF 55/487 reads (11%) | called by muse, mutect2, varscan2
- GTF2IRD1 | c.1869C>T p.L623= | Silent (SNP) | VAF 204/848 reads (24%) | called by muse, mutect2, varscan2
- IKZF1 | c.1410C>T p.L470= | Silent (SNP) | VAF 196/1349 reads (15%) | called by muse, mutect2, varscan2
- INTS6L | c.255G>A p.L85= | Silent (SNP) | VAF 174/378 reads (46%) | catalogued as rs1178495802; called by muse, mutect2, varscan2
- IRX5 | c.660A>C p.G220= | Silent (SNP) | VAF 50/756 reads (7%) | called by muse, mutect2
- ITPR3 | c.5013G>A p.Q1671= | Silent (SNP) | VAF 59/488 reads (12%) | called by muse, mutect2, varscan2
- KCNJ12 | c.501C>T p.I167= | Silent (SNP) | VAF 418/1554 reads (27%) | catalogued as rs781908591, COSV59165887; called by muse, varscan2
- KRT80 | c.138C>T p.L46= | Silent (SNP) | VAF 316/1306 reads (24%) | catalogued as COSV57549278; called by muse, mutect2, varscan2
- KRT86 | c.699C>A p.I233= | Silent (SNP) | VAF 53/683 reads (8%) | called by muse, mutect2
- LRRC8E | c.1296C>T p.T432= | Silent (SNP) | VAF 205/427 reads (48%) | catalogued as rs774461112; called by muse, mutect2, varscan2
- MARCKSL1 | c.28C>A p.R10= | Silent (SNP) | VAF 75/844 reads (9%) | catalogued as rs747118749; called by muse, mutect2
- MDC1 | c.1167C>T p.V389= | Silent (SNP) | VAF 34/1106 reads (3%) | called by muse, mutect2
- MIA2 | c.2412C>T p.T804= | Silent (SNP) | VAF 184/184 reads (100%) | called by mutect2, varscan2
- MYH7B | c.3384C>A p.L1128= | Silent (SNP) | VAF 53/499 reads (11%) | called by muse, mutect2, varscan2
- MYO3A | c.654C>T p.I218= | Silent (SNP) | VAF 49/448 reads (11%) | catalogued as COSV56327831; called by muse, mutect2, varscan2
- NBPF11 | c.369G>A p.L123= | Silent (SNP) | VAF 84/771 reads (11%) | called by muse, mutect2, varscan2
- NOP14 | c.477G>A p.E159= | Silent (SNP) | VAF 36/233 reads (15%) | called by muse, mutect2, varscan2
- NPM2 | c.519G>A p.A173= | Silent (SNP) | VAF 101/249 reads (41%) | catalogued as rs1287038846, COSV99235808; called by muse, mutect2, varscan2
- OR6J1 | c.1035C>T p.L345= | Silent (SNP) | VAF 189/189 reads (100%) | called by muse, mutect2, varscan2
- OTUD6B | c.48G>A p.L16= | Silent (SNP) | VAF 101/316 reads (32%) | called by muse, mutect2, varscan2
- PCDHGA10 | c.1980C>A p.A660= | Silent (SNP) | VAF 182/934 reads (19%) | called by muse, mutect2, varscan2
- PLPP5 | c.345C>T p.R115= | Silent (SNP) | VAF 26/170 reads (15%) | called by muse, mutect2, varscan2
- PRDM2 | c.2667G>A p.Q889= | Silent (SNP) | VAF 262/468 reads (56%) | called by muse, mutect2, varscan2
- PTDSS2 | c.6G>A p.R2= | Silent (SNP) | VAF 182/378 reads (48%) | called by muse, mutect2, varscan2
- ROS1 | c.6417T>C p.T2139= | Silent (SNP) | VAF 76/678 reads (11%) | called by muse, mutect2, varscan2
- ROS1 | c.1638C>G p.V546= | Silent (SNP) | VAF 70/1102 reads (6%) | called by muse, mutect2
- RRH | c.318T>A p.I106= | Silent (SNP) | VAF 114/242 reads (47%) | called by mutect2, varscan2
- SIGLEC10 | c.882C>G p.V294= | Silent (SNP) | VAF 80/850 reads (9%) | catalogued as rs1342898622; called by muse, mutect2
- SMC4 | c.1215A>G p.K405= | Silent (SNP) | VAF 333/443 reads (75%) | called by muse, mutect2, varscan2
- SRGAP2 | c.2124G>A p.S708= (on ENST00000624873 / NM_001170637.4; = p.S709= on NM_015326.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 53/609 reads (9%) | catalogued as rs781968270; called by muse, mutect2
- SRRM2 | c.1896A>G p.R632= | Silent (SNP) | VAF 65/699 reads (9%) | catalogued as rs1290216855; called by muse, mutect2
- SULT4A1 | c.282G>A p.P94= | Silent (SNP) | VAF 72/915 reads (8%) | catalogued as rs200810567; called by muse, mutect2
- TBX5 | c.534A>G p.K178= | Silent (SNP) | VAF 29/434 reads (7%) | called by muse, mutect2
- TKTL2 | c.1425A>C p.R475= | Silent (SNP) | VAF 40/386 reads (10%) | called by muse, mutect2, varscan2
- TRIM26 | c.1536C>T p.Y512= | Silent (SNP) | VAF 381/981 reads (39%) | catalogued as rs1366502596; called by muse, mutect2, varscan2
- UBL4A | c.129G>A p.L43= | Silent (SNP) | VAF 16/356 reads (4%) | called by muse, mutect2
- UROC1 | c.858G>T p.L286= | Silent (SNP) | VAF 62/982 reads (6%) | called by muse, mutect2
- VSTM2L | c.471C>G p.V157= | Silent (SNP) | VAF 173/1086 reads (16%) | catalogued as COSV65096746; called by muse, mutect2, varscan2
- WDR12 | c.141C>T p.F47= | Silent (SNP) | VAF 55/409 reads (13%) | called by muse, mutect2, varscan2
- ZNF100 | c.819C>T p.S273= | Silent (SNP) | VAF 306/611 reads (50%) | catalogued as rs766540094; called by muse, mutect2, varscan2
- ZNF20 | c.1044C>T p.F348= | Silent (SNP) | VAF 82/735 reads (11%) | catalogued as COSV61998972; called by muse, mutect2, varscan2
- ZNF208 | c.1734G>A p.E578= | Silent (SNP) | VAF 96/413 reads (23%) | catalogued as COSV101237196; called by muse, mutect2, varscan2
- ZNF469 | c.3723G>A p.P1241= (on ENST00000437464; = p.P1269= on NM_001367624.2) | Silent (SNP) | VAF 958/1486 reads (64%) | catalogued as rs1271108512, COSV71258167; called by muse, mutect2, varscan2
- ZNF579 | c.1101G>A p.Q367= | Silent (SNP) | VAF 157/854 reads (18%) | called by muse, mutect2, varscan2
- ZNF771 | c.714T>A p.R238= | Silent (SNP) | VAF 84/1088 reads (8%) | called by muse, mutect2
- ZNF831 | c.4350G>A p.L1450= | Silent (SNP) | VAF 80/623 reads (13%) | called by muse, mutect2, varscan2
- C3orf52 | c.*232A>C | 3'UTR (SNP) | VAF 36/891 reads (4%) | called by muse, mutect2
- C3orf52 | c.*233G>T | 3'UTR (SNP) | VAF 34/894 reads (4%) | called by muse, mutect2
- KCNQ1 | c.1393+27092T>G | Intron (SNP) | VAF 289/290 reads (100%) | called by muse, mutect2, varscan2
- LEKR1 | c.*657G>A | 3'UTR (SNP) | VAF 110/660 reads (17%) | catalogued as COSV100738845; called by muse, mutect2, varscan2
- MC1R | c.*480C>T | 3'UTR (SNP) | VAF 58/1276 reads (5%) | called by muse, mutect2
- MGAT4A | c.*4115C>T | 3'UTR (SNP) | VAF 124/785 reads (16%) | called by muse, mutect2, varscan2
- SH3D19 | c.-502G>C | 5'UTR (SNP) | VAF 99/448 reads (22%) | called by muse, mutect2
- XIST | n.9844C>A | RNA (SNP) | VAF 21/485 reads (4%) | called by muse, mutect2
